CCDI case PBBWIB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8a68370f-d80e-4c46-8b6b-ec73a1647ec2

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.2 years (7,011 days).

Biospecimens (3 samples)
- Sample 0DJHDX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJHED: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJHH9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
